Gene-level copy-number profile of tumor specimen TCGA-GN-A8LN-01A from TCGA case TCGA-GN-A8LN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.2 years (24,896 days).
Specimen TCGA-GN-A8LN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.eac28321-2225-4cbf-b946-99c1c820511d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GN-A8LN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f21bb5c2-148e-466f-a7a9-8e683553fdff

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 876; copy number 2: 11,793; copy number 3: 16,507; copy number 4: 28,381; copy number 5: 1,409; copy number 6: 350; copy number 7: 76; copy number 8: 102; copy number 9: 66; copy number 10: 66; copy number 11: 177; copy number 12: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GN-A8LN-01A-11D-A371-01): tumor purity 0.86, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes: AL449423.1, CDKN2B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 315 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:34,651,457–34,832,612, 3 genes, copy number 9 (within-gene range 3–9): AC025754.2, RAI14, AC025754.1.
- chr5:62,776,877–63,981,043, 6 genes, copy number 12: ISCA1P1, AC113420.1, AC025445.1, AC008558.1, HTR1A, AC122707.1.
- chr11:10,507,894–11,243,715, 19 genes, copy number 10: MTRNR2L8, MIR4485, RNF141, IRAG1-AS1, LYVE1, IRAG1, Y_RNA, CTR9, EIF4G2, SNORD97, AC116535.1, ZBED5, ZBED5-AS1, AC069360.1, LINC02752, AC111188.1, AC111188.2, MTND5P21, KC877392.1.
- chr11:11,351,942–11,353,307, 2 genes, copy number 10: CSNK2A3, AC023946.1.
- chr20:142,590–675,802, 21 genes, copy number 10: DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2.
- chr20:1,317,571–1,393,096, 1 gene, copy number 11 (within-gene range 7–11): AL136531.2.
- chr20:1,325,405–1,393,164, 4 genes, copy number 11 (within-gene range 7–11): SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869.
- chr22:22,185,941–24,178,628, 172 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr22:37,952,607–39,104,067, 62 genes, copy number 9 (broad region; genes not listed).
- chr22:39,120,293–39,120,566, 1 gene, copy number 9: COX5BP7.
- chr22:43,400,331–43,560,063, 4 genes, copy number 10: LINC01639, MPPED1, BX546033.1, EFCAB6-AS1.
- chr22:49,853,844–50,245,023, 20 genes, copy number 10: ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL, TTLL8, MLC1, MOV10L1, AL034546.1, PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6.

Autosomal genes at a single copy (total copy number 1): 876. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
